Gene-level copy-number profile of tumor specimen C3N-01857-01 (profiled together with C3N-01857-02) from CPTAC case C3N-01857, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.6 years (25,423 days).
Specimen C3N-01857-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d7c348ab-96be-41bc-a3b9-4bc37f61416d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01857-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/e3c2f33f-4d20-4b04-8c0b-789eb0b2aba4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 62; copy number 2: 4,410; copy number 3: 1,082; copy number 4: 45,580; copy number 5: 347; copy number 6: 6,831; copy number 7: 10; copy number 10: 2; copy number 94: 2; copy number 131: 2; copy number 166: 2; copy number 231: 8; copy number 978: 8.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr9:21,209,189–21,240,005, 5 genes (within-gene range 0–2): IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14.
- chr9:21,321,300–21,385,398, 5 genes: IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2.
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:23,500,691–23,682,662, 4 genes: AL445623.2, SUMO2P2, AL445623.1, NOP56P2.
- chr9:23,894,990–23,956,444, 2 genes: AL365204.2, AL365204.3.
- chr9:24,905,469–25,089,151, 2 genes: RMRPP5, RN7SKP120.
- chr9:25,780,032–25,844,585, 1 gene: LINC01241.
- chr9:26,642,697–26,644,595, 1 gene: AL442639.1.
- chr9:26,903,372–26,947,242, 1 gene (within-gene range 0–1): PLAA.
- chr9:26,955,780–26,956,295, 1 gene (within-gene range 0–1): IFT74-AS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 24 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,474,973–13,825,079, 8 genes, copy number 978: LRRC38, AL354712.1, BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2.
- chr7:43,758,680–43,807,342, 2 genes, copy number 131: BLVRA, AC005189.1.
- chr7:50,304,068–50,405,101, 2 genes, copy number 94: IKZF1, AC124014.1.
- chr7:54,621,025–55,260,256, 10 genes, copy number 166–231: RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr9:40,223,285–40,266,845, 2 genes, copy number 10 (within-gene range 1–10): ANKRD20A2P, RNU6-1269P.

Autosomal genes at a single copy (total copy number 1): 62. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
